Somatic mutation profile of tumor specimen 0DS536 from CCDI case PBCHRS, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain stem; Age at diagnosis: 14.7 years (5,385 days).
Specimen 0DS536: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dafcf69d-0b85-4615-8096-83b91620ef4c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DS543 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9d9f0952-32e2-4995-bf36-6779dcee74e6

The open-access MAF lists 45 somatic variants for this specimen: 26 protein-altering or splice-affecting, 5 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Intron 6, 3'UTR 6, Silent 5, Splice Site 2, 5'UTR 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 283/869 reads (33%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.467G>C p.R156P | Missense Mutation (SNP) | VAF 304/440 reads (69%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.876); catalogued as rs371524413, CM984589, COSV52698013, COSV52700732, COSV52710835, COSV52891661; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ADCY8 | c.1537G>A p.G513S | Missense Mutation (SNP) | VAF 1274/1994 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs933040675, COSV53909361; called by muse, mutect2, varscan2
- ANKEF1 | c.734G>A p.G245E | Missense Mutation (SNP) | VAF 209/741 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs1182400260; called by muse, mutect2, varscan2
- DNAH3 | c.262C>T p.R88C | Missense Mutation (SNP) | VAF 388/821 reads (47%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.153); catalogued as rs202049953, COSV99770663; called by muse, mutect2, varscan2
- MRPL46 | c.665G>A p.R222Q | Missense Mutation (SNP) | VAF 292/600 reads (49%) | SIFT tolerated (0.14); PolyPhen benign (0.029); catalogued as rs572609825, COSV56899202; called by muse, mutect2, varscan2
- PRDM14 | c.1675G>A p.E559K | Missense Mutation (SNP) | VAF 232/1182 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.018); catalogued as rs1310647778; called by muse, mutect2, varscan2
- SETD1B | c.2308G>A p.G770S | Missense Mutation (SNP) | VAF 113/527 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs1230495334; called by muse, mutect2, varscan2
- SLC19A2 | c.1259A>G p.Y420C | Missense Mutation (SNP) | VAF 171/1042 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs760930109; called by muse, mutect2, varscan2
- TECPR2 | c.410C>G p.P137R | Missense Mutation (SNP) | VAF 333/855 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as rs764119429; called by muse, mutect2, varscan2
- ACTL7A | c.31G>T p.D11Y | Missense Mutation (SNP) | VAF 90/486 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- ASB15 | c.1709A>T p.Q570L | Missense Mutation (SNP) | VAF 167/1111 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 52/1458 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- DDX54 | c.815A>G p.H272R | Missense Mutation (SNP) | VAF 104/609 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNA2 | c.1873G>A p.G625S | Missense Mutation (SNP) | VAF 333/753 reads (44%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- DOP1B | c.1181C>A p.S394Y | Missense Mutation (SNP) | VAF 264/1254 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- HOXC11 | c.612G>T p.E204D | Missense Mutation (SNP) | VAF 123/604 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- L1CAM | c.2313dup p.F772Lfs*14 | Frame Shift Ins (INS) | VAF 67/180 reads (37%) | called by mutect2, varscan2
- MAST4 | c.6920C>T p.P2307L (on ENST00000403625 / NM_001164664.2; = p.P2118L on NM_015183.3) | Missense Mutation (SNP) | VAF 131/611 reads (21%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MED8 | c.125+2T>G p.X42_splice | Splice Site (SNP) | VAF 144/519 reads (28%) | called by muse, mutect2, varscan2
- MED8 | c.125+1G>A p.X42_splice | Splice Site (SNP) | VAF 146/530 reads (28%) | called by muse, mutect2, varscan2
- NLGN3 | c.2122T>G p.L708V (on ENST00000358741 / NM_181303.2; = p.L688V on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 136/302 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TECPR2 | c.305C>T p.A102V | Missense Mutation (SNP) | VAF 446/1074 reads (42%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TMEM150A | c.25G>A p.V9I | Missense Mutation (SNP) | VAF 212/914 reads (23%) | SIFT tolerated (0.84); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- ZNF510 | c.742C>G p.Q248E | Missense Mutation (SNP) | VAF 48/1318 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.014); called by muse, mutect2
- ZNF879 | c.1446A>C p.K482N | Missense Mutation (SNP) | VAF 11/354 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.017); called by muse, mutect2
- CEP170B | c.3738C>T p.T1246= (on ENST00000453495; = p.T1175= on NM_015005.3) | Silent (SNP) | VAF 157/350 reads (45%) | catalogued as rs1291014467; called by muse, mutect2, varscan2
- DRD2 | c.193C>T p.L65= | Silent (SNP) | VAF 138/375 reads (37%) | called by muse, mutect2, varscan2
- LRP1B | c.8373C>T p.S2791= | Silent (SNP) | VAF 330/677 reads (49%) | catalogued as rs528649164, COSV67224570, COSV67270382; called by muse, mutect2, varscan2
- LYPLA1 | c.51C>A p.A17= | Silent (SNP) | VAF 223/989 reads (23%) | called by muse, mutect2, varscan2
- USP24 | c.7485C>T p.R2495= | Silent (SNP) | VAF 122/685 reads (18%) | called by muse, mutect2, varscan2
- DCST2 | c.806-87T>C | Intron (SNP) | VAF 17/85 reads (20%) | called by muse, mutect2, varscan2
- DGKZ | c.*48C>T | 3'UTR (SNP) | VAF 20/172 reads (12%) | catalogued as rs763708366; called by muse, varscan2
- ENPP2 | c.1781-1257T>A | Intron (SNP) | VAF 61/445 reads (14%) | called by muse, mutect2, varscan2
- FAIM | c.*75T>G | 3'UTR (SNP) | VAF 8/242 reads (3%) | called by muse, mutect2
- FECH | c.314+73C>T | Intron (SNP) | VAF 26/135 reads (19%) | called by mutect2, varscan2
- GRIA4 | c.*18G>T | 3'UTR (SNP) | VAF 159/811 reads (20%) | catalogued as rs1184410495; called by muse, mutect2, varscan2
- ITGAX | c.*33C>T | 3'UTR (SNP) | VAF 45/183 reads (25%) | catalogued as rs750555331, COSV99191862; called by muse, mutect2, varscan2
- LINC00662 | n.601+16059del | Intron (DEL) | VAF 58/244 reads (24%) | catalogued as rs199911463; called by mutect2, varscan2
- MTDH | c.-90C>T | 5'UTR (SNP) | VAF 66/100 reads (66%) | called by muse, mutect2
- PGLS | c.288+730G>A | Intron (SNP) | VAF 36/181 reads (20%) | called by muse, mutect2, varscan2
- PLCL1 | c.*40A>G | 3'UTR (SNP) | VAF 60/183 reads (33%) | called by muse, mutect2, varscan2
- POLR3H | c.*1243G>A | 3'UTR (SNP) | VAF 151/472 reads (32%) | called by muse, mutect2, varscan2
- PSG1 | c.1243+19C>T | Intron (SNP) | VAF 148/798 reads (19%) | catalogued as rs776428606, COSV54953875; called by muse, mutect2, varscan2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 28/292 reads (10%) | called by muse, varscan2
